Surgical pathology report (de-identified scan), TCGA case TCGA-EE-A3J8, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Sydney, specimen TCGA-EE-A3J8-06A (Metastatic).

[page 1 of 2]
DOB/Age/Sex:
Location:
Requested by:
Requested on:
Specimen Rcvd:
Accession No.:
Copies to:

HISTOPATHOLOGY REPORT

REFERRED MRN

ICD-0-3
Melanoma, NOS 8720/3
Site: Subcutaneous, axilla C49.3
lw 4/10/12

CLINICAL DETAILS

Excision 2 x metastasis L axilla region. Known metastatic melanoma.
2 palpable nodules (1) anterior, (2) posterior. ?Confirm melanoma.
2 nodules, subcut.
Small slice taken for tumour banking.

MACROSCOPIC DESCRIPTION

(Dr

Primary Tumour Site Discrepancy		☒

Two specimens were received.

1. "TUMOUR LEFT AXILLA POSTERIOR". Please note the discrepancy between labels on the request form and labels on the container. An unoriented half of skin ellipse 23 x 14 x 12mm in depth. The specimen was previously bisected for tumour banking. The deep margin inked blue. The cut surface shows a well defined round mass 16 x 13 x 12mm tan and firm in consistency. Three slices of the entire lesion embedded in blocks A-F.

A&B. One slice
C&D. One slice
E&F. One slice

2. "TUMOUR LEFT AXILLA ANTERIOR". Please note the discrepancy between labels on the request form and labels on the container. An unoriented half ellipse of skin 33 x 21 x 12mm in depth. The cut surface shows subcutaneous nodule 9 x 7 x 6mm tan white in colour, firm in consistency almost abutting the deep margin. Four slices of the entire lesion embedded in blocks A-D.

MICROSCOPIC REPORT

1. "TUMOUR LEFT AXILLA POSTERIOR"

The sections show skin to the level of subcutis and skeletal muscle. Within the subcutis is a relatively well defined, unencapsulated tumour nodule. The tumour is composed of pleomorphic epithelioid cells, with high nuclear: cytoplasmic ratio, hyperchromatic oval nuclei with prominent nucleoli and with a brisk mitotic rate. No intracytoplasmic pigment is seen. The tumour lies 4mm from the closest (deep) margin. S100 is positive (nuclear and cytoplasmic, patchy strong staining), Melan A and HMB45 are negative. The skin is unremarkable. The features are of metastatic melanoma.

2. "TUMOUR LEFT AXILLA ANTERIOR"

The sections show skin to the level of subcutis and skeletal muscle, containing a tumour nodule with similar morphological features to specimen 1. The tumour lies 0.3mm from the closest radial margin. The features are of metastatic melanoma. The skin is unremarkable.

[page 2 of 2]
Requested by:

MRN/Name:

Location:

Accession:

HISTOPATHOLOGY REPORT

SUMMARY

1. Soft tissue, left axilla posterior - Metastatic melanoma.
/
2. Soft tissue, left axilla anterior - Metastatic melanoma.

REPORTED BY: Dr.

Source: NCI Genomic Data Commons file fc5da0bc-548e-48f9-aa87-ea942877426f (TCGA-EE-A3J8.5A6AD064-C665-4D44-A683-495680AB17B6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).